Gene-level copy-number profile of tumor specimen REBC-AC9L-TTP1-A from REBC case REBC-AC9L, project REBC-THYR (Comprehensive genomic characterization of radiation-related papillary thyroid cancer in the Ukraine). Sex at birth: female; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland.
Specimen REBC-AC9L-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c743e285-e7df-4566-9b7f-94ee33080063.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator REBC-AC9L-NT1-A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,235 have no estimate.
https://portal.gdc.cancer.gov/files/cdf444b4-e6d3-4bab-a5ab-990ee0c88645

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 22; copy number 1: 1,540; copy number 2: 56,240; copy number 3: 560; copy number 4: 23; copy number 5: 3.

Homozygous deletions (total copy number 0; autosomes only): 22 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:219,327,407–219,333,177, 1 gene: RESP18.
- chr3:48,306,842–48,328,341, 2 genes: SPINK8, MIR2115.
- chr3:184,086,791–184,117,898, 4 genes: Y_RNA, HTR3E-AS1, HTR3E, HSP90AA5P.
- chr4:88,201,703–88,226,829, 4 genes (within-gene range 0–2): RNU6-818P, RNU6ATAC31P, AC097484.2, RNU6-1298P.
- chr11:125,495,214–125,499,528, 1 gene (within-gene range 0–2): AP000708.1.
- chr13:52,167,709–52,334,277, 5 genes (within-gene range 0–2): MRPS31P5, AL158066.1, THSD1P1, AL158066.2, TPTE2P2.
- chr15:74,461,265–74,516,959, 4 genes (within-gene range 0–2): UBL7-AS1, AC012435.2, AC012435.3, AC012435.1.
- chr22:29,438,583–29,442,455, 1 gene (within-gene range 0–2): RFPL1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:160,995,211–161,021,343, 1 gene, copy number 5 (within-gene range 2–5): F11R.
- chr12:57,869,834–57,896,846, 2 genes, copy number 5: AC083805.1, AC083805.3.

Autosomal genes at a single copy (total copy number 1): 1,466. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
